Gene-level copy-number profile of tumor specimen TCGA-S8-A6BW-01A from TCGA case TCGA-S8-A6BW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 51.9 years (18,944 days).
Specimen TCGA-S8-A6BW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.8b64619d-bb0a-4c33-97a8-18846ce82fcf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S8-A6BW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64c76542-7fa9-4ce2-8e26-7988bb1b2d0d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,089; copy number 2: 15,993; copy number 3: 15,943; copy number 4: 22,357; copy number 5: 1,722; copy number 6: 1,033; copy number 7: 593; copy number 8: 305; copy number 11: 153; copy number 13: 89; copy number 14: 396; copy number 16: 75; copy number 19: 41; copy number 24: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S8-A6BW-01A-11D-A31T-01): tumor purity 0.58, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 775 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:38,682,070–38,845,829, 4 genes, copy number 11: AC010425.1, OSMR-AS1, AC091435.1, AC091435.2.
- chr8:35,862,123–43,674,591, 187 genes, copy number 13–24 (within-gene range 4–24) (broad region; genes not listed).
- chr9:24,905,469–43,045,120, 435 genes, copy number 11–14 (broad region; genes not listed).
- chr12:64,186,316–67,978,387, 85 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr12:68,001,394–68,036,853, 2 genes, copy number 11: RPL39P28, HNRNPA1P70.
- chr12:68,686,951–68,745,809, 1 gene, copy number 19 (within-gene range 6–19): NUP107.
- chr12:68,746,125–71,800,286, 61 genes, copy number 11–19 (within-gene range 2–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,089. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
